Gene-level copy-number profile of tumor specimen C3L-10083-01 from CPTAC case C3L-10083, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 53.5 years (19,526 days).
Specimen C3L-10083-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d28f4240-f137-4595-8d51-8985b223ae6d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-10083-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/6dd39b33-9d63-48b2-b731-5db010cab4f9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 529; copy number 1: 4,365; copy number 2: 25,271; copy number 3: 17,909; copy number 4: 6,744; copy number 5: 2,223; copy number 6: 790; copy number 7: 118; copy number 8: 359; copy number 9: 210; copy number 10: 50; copy number 16: 236; copy number 18: 98.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr16:78,495,926–78,553,296, 4 genes (within-gene range 0–2): AC046158.1, AC046158.4, AC046158.2, AC046158.3.
- chr20:14,352,320–14,352,425, 1 gene (within-gene range 0–1): RNU6-228P.
- chr20:14,547,184–14,758,056, 3 genes (within-gene range 0–1): RNF11P2, MACROD2-IT1, RPS10P2.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–1): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,045 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–156,082,465, 577 genes, copy number 5–6 (broad region; genes not listed).
- chr1:168,695,468–169,460,669, 15 genes, copy number 7: DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1, CCDC181.
- chr1:181,190,471–181,191,149, 1 gene, copy number 8: AL358393.1.
- chr1:185,518,651–187,686,628, 20 genes, copy number 5 (within-gene range 4–5): AL133383.2, LINC01350, Y_RNA, Y_RNA, AL133383.1, HMCN1, AL133553.1, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, PTGS2, PACERR, PLA2G4A, LINC01036.
- chr1:204,422,628–233,385,148, 597 genes, copy number 5–9 (within-gene range 4–9) (broad region; genes not listed).
- chr2:27,996,367–28,644,142, 12 genes, copy number 5 (within-gene range 3–5): MIR4263, FAM133EP, AC096552.1, AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7.
- chr2:65,070,696–65,271,253, 5 genes, copy number 6 (within-gene range 3–6): RAB1A, SNORA74, AC007318.1, VDAC2P5, ACTR2.
- chr2:189,311,263–192,645,706, 51 genes, copy number 7 (within-gene range 3–7): KRT18P19, WDR75, KDM3AP1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1, TMEFF2, AC062039.1.
- chr2:218,944,629–219,684,795, 59 genes, copy number 6: AC097468.2, KRT8P30, CDK5R2, LINC00608, FEV, CRYBA2, MIR375, AC097468.1, CFAP65, IHH, MIR3131, AC097468.3, NHEJ1, AC068946.1, RN7SL764P, SLC23A3, CNPPD1, RETREG2, ZFAND2B, AC068946.3, ABCB6, AC068946.2, ATG9A, ANKZF1, GLB1L, STK16, TUBA4A, TUBA4B, DNAJB2, PTPRN, MIR153-1, AC114803.1, RESP18, AC053503.2, DNPEP, AC053503.1, DES, AC053503.3, AC053503.5, SPEG, ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA, ASIC4, CHPF, TMEM198, AC009955.3, MIR3132, OBSL1, AC009955.4, INHA, RN7SKP213, STK11IP, AC009955.1, SLC4A3, AC009955.2, DNAJB6P3.
- chr3:32,951,644–35,256,946, 26 genes, copy number 5: CCR4, GLB1, SEC13P1, SUMO2P10, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.1, AC018359.1, FECHP1, KRT8P18, RNU6-243P.
- chr3:149,318,498–149,433,274, 6 genes, copy number 6 (within-gene range 3–6): TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2.
- chr6:38,675,925–58,438,364, 376 genes, copy number 10–18 (broad region; genes not listed).
- chr6:166,209,403–170,738,536, 106 genes, copy number 8 (broad region; genes not listed).
- chr8:74,048,677–89,243,793, 204 genes, copy number 9 (broad region; genes not listed).
- chr8:89,585,872–101,262,903, 224 genes, copy number 8–10 (broad region; genes not listed).
- chr8:127,079,874–127,092,600, 2 genes, copy number 5: PRNCR1, AC020688.1.
- chr9:41,233,755–41,764,175, 21 genes, copy number 5: MIR4477A, RNA5SP530, AL845472.1, PTGER4P2-CDK2AP2P2, CDK2AP2P1, MYO5BP1, AL354718.2, CDRT15P6, AL354718.1, AL591926.3, SNORA70, RN7SL565P, AL591926.7, AL591926.6, AL591926.5, AL591926.2, FAM242F, Y_RNA, AL591926.1, AL591926.4, AL162731.1.
- chr9:60,914,407–61,453,030, 12 genes, copy number 8: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr9:63,581,254–66,179,474, 60 genes, copy number 5–7: AL591438.1, AL591438.2, CDRT15P7, AL772155.1, AL772155.2, MYO5BP3, CDK2AP2P3, PTGER4P3, CR786580.1, RNA5SP284, DUX4L50, MIR4477B, FRG1JP, AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P, BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1, FOXD4L5, CBWD4P, Y_RNA, FRG1KP, CBWD5, FOXD4L4, IGKV1OR-3, BX284632.2, BX284632.1, BMS1P13, AC129778.1, AQP7P3, AL136317.2, AL136317.1, GXYLT1P4, AL136317.3, AL669942.2, AL669942.1, AL513478.4, SNX18P4, AL513478.1, ANKRD20A3P, RNU6-538P.
- chr10:31,756,042–32,394,665, 19 genes, copy number 5: Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P.
- chr10:32,511,336–32,511,737, 1 gene, copy number 5: C1DP1.
- chr12:55,954,105–56,190,284, 24 genes, copy number 8: PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4.
- chr12:116,738,178–119,303,380, 49 genes, copy number 5: RNFT2, AC090013.1, RNU6-558P, AC083806.3, HRK, AC083806.1, FBXW8, AC083806.2, AC127164.1, AC026368.1, TESC, TESC-AS1, FBXO21, NOS1, ELOCP32, AC073864.1, KSR2, AC084291.1, RFC5, AC131159.2, WSB2, AC131159.1, VSIG10, AC131238.1, PEBP1, TAOK3, RPS2P5, AC026367.1, SUDS3, AC026367.3, AC026367.2, LINC02460, RPL17P37, LINC02423, LINC02440, LINC02439, RNA5SP374, AC087863.2, AC087863.1, SRRM4, AC087885.1, RN7SL508P, AC084361.1, HSPB8, AC084880.4, AC084880.3, AC084880.1, AC084880.2, LINC00934.
- chr12:119,685,791–121,399,896, 72 genes, copy number 5–7 (broad region; genes not listed).
- chr13:93,226,807–94,408,020, 2 genes, copy number 5 (within-gene range 3–5): GPC6, AL160159.1.
- chr13:93,818,424–99,200,757, 77 genes, copy number 5 (broad region; genes not listed).
- chr13:101,053,776–114,337,626, 184 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr15:90,634,725–99,105,824, 156 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr15:100,344,047–101,979,093, 64 genes, copy number 5 (broad region; genes not listed).
- chr17:82,239,023–83,240,804, 49 genes, copy number 5: CSNK1D, AC132872.3, AC132872.4, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3, AC124283.2, AC124283.1, WDR45B, AC124283.5, RAB40B, MIR4525, AC024361.2, FN3KRP, AC024361.3, FN3K, AC024361.1, TBCD, AC068014.1, ZNF750, AC087222.1, B3GNTL1, AC130371.1, METRNL, AC130371.2, AC144831.1, AC139099.3, AC139099.2, AC139099.1, RPL23AP87.
- chr18:45,034–11,149,569, 223 genes, copy number 5–7 (broad region; genes not listed).
- chr18:20,946,906–22,419,294, 40 genes, copy number 5: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1.
- chr19:27,638,483–40,950,660, 503 genes, copy number 5–6 (broad region; genes not listed).
- chr20:17,693,672–20,360,703, 58 genes, copy number 5 (within-gene range 4–5): BANF2, AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1.
- chr20:33,079,644–33,650,036, 14 genes, copy number 6: BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2.
- chr20:35,558,737–35,674,544, 8 genes, copy number 5 (within-gene range 4–5): FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12.
- chr20:46,859,333–49,036,693, 40 genes, copy number 6: RN7SKP33, AL354766.1, EYA2, AL354766.2, GAPDHP54, AL121776.1, AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P, NCOA3, AL034418.1, SULF2, AL354813.1, RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, LINC01522, LINC01523, AL139351.1, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1, ARFGEF2.
- chr20:50,162,765–50,691,542, 19 genes, copy number 5: LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1.
- chr20:51,782,331–56,602,113, 60 genes, copy number 6: SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, LINC01716, RPS4XP3.
- chr20:57,488,392–57,525,652, 2 genes, copy number 5: HMGB1P1, CTCFL.

Autosomal genes at a single copy (total copy number 1): 3,072. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
